Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A1OD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A1OD-01A (Primary Tumor).

[page 1 of 4]
ICA-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: cervix, NOS C53.9 3/4/11 fur

Attending MD:
Ordering MD:
Copies To:

DIAGNOSIS: ***ADDENDUM***

1. RIGHT PELVIC LYMPH NODE, BIOPSY:
- No tumor identified in four lymph nodes (0/4)
- Sinus histiocytes and focal intraparenchymal acute inflammation
2. RIGHT COMMON ILIAC NODE, BIOPSY:
- No tumor identified in one lymph node (0/1)
- Sinus histiocytes present
3. UTERUS, RADICAL HYSTERECTOMY:
- Poorly differentiated invasive squamous cell carcinoma of uterine cervix, large cell, focally keratinizing
- The maximal thickness of the cervical stromal invasion is 19 mm
- The maximal superficial spread of the tumor is 22 mm
- The invasive squamous cell carcinoma involves all four quadrants of the cervix
- Diffuse CIN III/CIS with gland duct involvement and focal HPV changes are also present
- Few foci suspicious for lymphovascular space invasion present
- Focal vaginal extension (upper third, posterior) is present
- The anterior and posterior lower uterine segment show no evidence of involvement
- No parametrial involvement is identified
- All inked surgical excision margins (paracervical soft tissue and vaginal margins) are free from involvement
- Associated acute and chronic cervicitis with squamous metaplasia, nabothian cysts, focal calcific atherosclerosis and ciliated cell metaplasia are also present
- The endometrium is unremarkable and shows early secretory changes
- The myometrium shows multiple leiomyomata (4) with evidence of hyalinization and focal degenerative necrosis (largest leiomyoma measuring 4.5 cm) and focal adenomyosis

(continued on next page)

Page: 2

- 4: OBTURATOR NODE, BIOPSY:
- No tumor identified in four lymph nodes (0/4)
- 5: RIGHT TUBE AND OVARY, RIGHT SALPINGO-OOPHORECTOMY:
- Right ovary showing diminutive fibroma (0.7 cm in greatest dimension), simple cyst, follicular cyst, involuting corpus luteum, stromal hyperplasia, surface stromal proliferations, surface adhesions, and focal surface epithelial inclusion cyst
- Right fallopian tube shows no significant histopathologic changes
- No malignancy is identified

[page 2 of 4]
- 6: LEFT TUBE AND OVARY, LEFT SALPINGO-OOPHORECTOMY:
-Left ovary showing hemorrhagic corpus luteum, follicle cysts, atretic follicles, surface epithelial inclusion cysts, surface adhesions and focal surface stromal proliferations
-Left fallopian tube showing mesonephric duct remnants
- 7: LEFT COMMON ILIAC NODE, BIOPSY:
-No tumor identified in four lymph nodes (0/4)
- 8: LEFT PELVIC LYMPH NODE, BIOPSY:
-No tumor identified in three lymph nodes (0/3)
-Reactive lymph nodes showing sinus histiocytes and focal intraparenchymal acute inflammation

NOTE: Based on the material examined, this tumor is at least AJCC stage IB1, T1b1 NO Mx.

ADDENDUM

Although, accurate estimation of depth of invasion of the carcinoma is precluded by suboptimal sections, in some sections it appears to be greater than 50% invasion of the cervical wall. Foci of, definite and other foci suspicious for lymphovascular space invasion are present. Dr. has reviewed representative sections of this case.

=====

HISTORY: Ovarian carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: RIGHT PELVIC NODE

Labeled "right pelvic node" and received in formalin is 4.8 x 4.5 x 2.4 cm aggregate of adipose tissue which contains four firm, tan-pink lymph nodes ranging from 1.1 up to 2.6 cm in greatest dimension. All lymph nodes are entirely submitted as labeled.

- A. Smaller nodes - 2
- B. Mid size lymph node bisected - 2
- C. Largest lymph node bisected - 2

2: RIGHT COMMON ILIAC NODE

Labeled "right common iliac node" and received in formalin is a 1.9 x (continued on next page)

0.9 x 0.3 cm soft, tan-pink lymph node which is entirely submitted.

D. 1

3: UTERUS

Labeled "uterus", received fresh in the Operating Room for gross consultation and subsequently fixed in formalin is a 420 gram, uterus with attached cervix. The uterus is 13.1 cm from fundus to ectocervix, 8.1 cm from cornu to cornu, and 6.1 cm from anterior to posterior. The serosa is tan-red and dull with focal adhesions. The cervix is 4.2 cm in length and 4.1 cm in diameter with a 0.3 cm patent os. There is a cuff of vaginal mucosa ranging in thickness from 1.7 cm anteriorly to 3.1 cm posteriorly. The ectocervical mucosa is tan-pink and smooth. On sectioning, the transformation zone is distinct and the endocervical canal is 3.0 cm in length. Along the transformation zone and ectocervix is a 2.0 x 2.0 cm granular and hemorrhagic area. The paracervical soft tissue and vaginal margins are inked blue. The endometrial cavity is 7.4 cm in length and 1.6 cm in width and is lined by smooth, tan-red

Page: 3

[page 3 of 4]
endometrium. The endometrium is 0.1 cm in average thickness. The myometrium measures up to 5.2 cm in thickness and contains four intramural leiomyomata ranging from 0.5 up to 4.5 cm in greatest dimension. On sectioning, the largest leiomyomata displays central areas of hemorrhage and necrosis. Representative sections.

- E. Smaller leiomyomata - 3
- F. Largest leiomyoma with central necrosis - 2
- G. Anterior uterine corpus - 1
- H. Anterior lower uterine segment - 1
- I-O. Entire anterior cervix - 1 each
- P. Posterior uterine corpus - 1
- Q. Posterior lower uterine segment - 1
- R-U. Entire posterior cervix - 1 each

4: OBTURATOR

Labeled "obturator" and received in formalin is a 2.1 x 1.7 x 0.3 cm portion of soft tan-yellow adipose tissue which is entirely submitted.

V. Multiple

5: RIGHT TUBE OVARY

Labeled "right tube ovary" and received in formalin is a 4.1 cm in length and 0.5 cm in diameter fimbriated segment of fallopian tube. The serosa is tan-pink with moderate tubo-ovarian adhesions. On sectioning, cut surface is focally edematous with a 0.2 cm patent lumen. The fallopian tube is adherent to a 2.6 x 2.1 x 1.9 cm firm, tan-yellow cerebriform ovary. On sectioning, the cut surface displays two unilocular cysts which contain a minimal amount of clear serous fluid. The cystic locules are 0.5 and 1.7 cm in greatest dimension. The inner cyst linings are smooth without papillary excrescences. There is a 0.4 cm in greatest dimension firm yellow nodule on the external surface. Representative sections.

- W. Fallopian tube and cysts - 3
- X. Larger cyst wall - 3
- Y. Ovarian parenchyma with external surface nodule - 1

(continued on next page)

Page: 4

6: LEFT TUBE OVARY

Labeled "left tube and ovary" and received in formalin is a 3.7 cm in length and 0.6 cm in diameter fimbriated segment of fallopian tube. The serosa is tan-pink and smooth. On sectioning, cut surfaces are focally edematous with a 0.2 cm patent lumen. The fallopian tube is adherent to a 3.6 x 1.7 cm lobulated and focally cerebriform ovary with focal hemorrhage. On sectioning, two unilocular clear fluid-filled cysts are identified which are 0.7 and 1.0 cm in greatest dimension. No papillary excrescences are identified. There is also a 2.2 cm in greatest dimension hemorrhagic area. Representative sections.

- Z. Fallopian tube and smaller cyst - 3
- AA. Larger cyst - 2
- BB. Hemorrhagic area - 3
- CC. Random ovary - 1

7: LEFT COMMON ILIAC

Labeled "left common iliac" and received in formalin are four firm, tan-pink lymph nodes ranging from 0.6 up to 1.7 cm in greatest dimension. All lymph node tissue is entirely submitted as labeled.

- DD. Lymph nodes (largest node bisected) - 4

8: LEFT PELVIC NODE

Labeled "left pelvic node" and received in formalin is a 3.6 x 2.7 x

[page 4 of 4]
1.2 cm aggregate of lobulated adipose tissue which contains three firm, tan-pink lymph nodes ranging from 0.5 up to 1.7 cm in greatest dimension. All lymph node tissue is entirely submitted as labeled.

EE. Three lymph nodes (largest node bisected) - 4

Gross dictated by

OPERATIVE CONSULT (GROSS):

3. Localized friable hemorrhagic area in cervix approximately 2.0 x 2.0 cm. A small portion (0.8 x 0.1 cm) of friable lesion is given fresh for Dr. research study

(
Special Studies: Frozen Section
See Also:

, M.D.
Pathologist

I, M.D., the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled:

I, M.D., the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

(continued on next page)

Page: 5

Source: NCI Genomic Data Commons file 165f4ba4-78be-4883-9ad5-df835a46d34a (TCGA-DS-A1OD.81536C16-0708-483D-AAE9-DD3477D85177.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).